Surgical pathology report (de-identified scan), TCGA case TCGA-KS-A4I7, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Of Michigan, specimen TCGA-KS-A4I7-01A (Primary Tumor).

[page 1 of 3]
ICD-0-3

Carcinoma, papillary, thyroid 8260/3

Sets: thyroid, NOS 10/1/12
C73.9

PROCEDURE: SPHS

VERIFIED BY: [REDACTED]

Thyroid cancer and primary hyperparathyroidism. Operative Procedure/Tissue
Submitted: Parathyroidectomy; total thyroidectomy with central neck
dissection.

PROCEDURE: SPGD

VERIFIED BY: [REDACTED]

1. "Total thyroid." Received in formalin is a 20 gm, thyroid, with a 5 x 3 x
1.5 cm right lobe, a 4.5 x 3 x 2 cm left lobe and a 1 x 2 x 0.6 cm isthmus.

[page 2 of 3]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:

PAGE #:

2

BIRTHDATE:

PAT TYPE:

SEX: F

ADM DATE:

OPER DATE:

The outer surface capsule is smooth and intact. Specimen is inked left lobe blue, right lobe green, isthmus yellow. Serial sectioning of the left lobe reveals a 1.5 x 1 x 1.2 cm nodule in the inferior left lobe. The nodule grossly abuts the capsule on the anterior. The remainder of the left lobe parenchyma shows uniform, dark red parenchyma. Serial sectioning of the right lobe reveals uniform, beefy red parenchyma. Sectioning of the isthmus reveals uniform beefy red parenchyma.

1A-B. Representative sections of inferior left lobe mass.

1C. Representative sections of apparently uninvolved superior left lobe.

1D-E. Representative sections of right lobe.

1F. Representative sections of isthmus.

2. "Left upper parathyroid." Received in formalin in a small container is a 1.2 x 1 x 0.5 cm, lobular, pink tissue. Bisected.

3. "Level VI lymph node." Received in formalin in a small container are three portions of fibroadipose tissue measuring in aggregate 2.2 x 1.5 x 0.5 cm. Two lymph nodes identified within the fibroadipose tissue.

3A. Two lymph nodes. Fat retained.

PROCEDURE: SPMI

PAPILLARY THYROID CARCINOMA

Size of largest primary tumor: 1.5 cm.

Location(s): Left lobe.

Capsular Invasion: No.

Vascular Invasion: No.

Margins: Negative.

Extrathyroidal extension: No.

Lymph node metastases: No.

Extranodal extension: N.A.

SIDE	LEVEL	#POSITIVE NODES	#TOTAL NODES
Central	VI and perithyroidal	0	4

[page 3 of 3]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:

PAGE #:

3

BIRTHDATE:

PAT TYPE:

SEX: F

ADM DATE:

OPER DATE:

PROCEDURE: SPDX

1. Thyroid, resection: Intracystic papillary thyroid carcinoma (1.5 cm), arising in the left lobe. Three benign lymph nodes. Please see TEMPLATE for details.

2. Parathyroid, left upper, resection: Benign parathyroid gland.

3. Lymph nodes, level VI, resection: One benign lymph node. Ectopic thyroid tissue.

I, [REDACTED] the signing staff pathologist, have personally examined and interpreted the slides from this case.

Code:

Source: NCI Genomic Data Commons file 2d577bd2-477a-4d85-8379-e422edaced82 (TCGA-KS-A4I7.819E8C9B-A49F-450A-A55D-19BF97E3F9ED.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).